Somatic mutation profile of tumor specimen 0DU9MW from CCDI case PBCKRZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.0 years (361 days).
Specimen 0DU9MW: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1c48df5f-6298-4b88-abdd-dfc42ec3208a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DU9ND (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/305caeef-33ac-45cc-aaf3-7e1e90e9efb7

The open-access MAF lists 46 somatic variants for this specimen: 21 protein-altering or splice-affecting, 25 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 21, Missense Mutation 16, 3'UTR 3, Nonsense Mutation 2, 5'UTR 1, Splice Region 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKT3 | c.629C>A p.S210Y | Missense Mutation (SNP) | VAF 22/173 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.035); catalogued as COSV55608355; called by muse, varscan2
- DACH2 | c.1711G>A p.E571K | Missense Mutation (SNP) | VAF 24/193 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV100913734, COSV64177967; called by muse, varscan2
- KIF13A | c.1139A>T p.Q380L | Missense Mutation (SNP) | VAF 18/494 reads (4%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.465); catalogued as rs1252217511; called by muse, mutect2
- MS4A2 | c.31del p.A12Lfs*28 | Frame Shift Del (DEL) | VAF 35/438 reads (8%) | catalogued as COSV54012248, COSV54013880; called by muse*, mutect2
- ZBED5 | c.1832T>G p.L611R | Missense Mutation (SNP) | VAF 25/234 reads (11%) | SIFT tolerated (0.52); PolyPhen benign (0.063); catalogued as rs780011941; called by muse, varscan2
- ZNF578 | c.1619A>T p.K540I | Missense Mutation (SNP) | VAF 30/273 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs753524966; called by muse, varscan2
- BMX | c.100A>G p.T34A | Missense Mutation (SNP) | VAF 35/272 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- CCDC138 | c.561A>G p.I187M | Missense Mutation (SNP) | VAF 28/257 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, varscan2
- CCDC18 | c.3880A>T p.K1294* (on ENST00000343253 / NM_001306076.1; = p.K1295* on NM_206886.4) | Nonsense Mutation (SNP) | VAF 53/210 reads (25%) | called by muse, varscan2
- CLSPN | c.28C>A p.H10N | Missense Mutation (SNP) | VAF 20/185 reads (11%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.028); called by muse, varscan2
- COL14A1 | c.1840C>G p.P614A | Missense Mutation (SNP) | VAF 42/522 reads (8%) | SIFT tolerated (0.83); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- COPG2 | c.738-6T>A | Splice Region (SNP) | VAF 35/264 reads (13%) | called by muse, varscan2
- FER1L6 | c.5042T>A p.L1681* | Nonsense Mutation (SNP) | VAF 38/368 reads (10%) | called by muse, varscan2
- KBTBD3 | c.436A>T p.I146L | Missense Mutation (SNP) | VAF 38/414 reads (9%) | SIFT tolerated (0.67); PolyPhen benign (0.17); called by mutect2, varscan2
- MALSU1 | c.701A>C p.E234A | Missense Mutation (SNP) | VAF 24/204 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.265); called by muse, varscan2
- PSMA4 | c.209+2T>A p.X70_splice | Splice Site (SNP) | VAF 38/356 reads (11%) | called by muse, varscan2
- UTY | c.2804C>T p.T935I | Missense Mutation (SNP) | VAF 20/152 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, varscan2
- VPS13A | c.3211A>T p.N1071Y | Missense Mutation (SNP) | VAF 53/382 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.257); called by muse, varscan2
- ZBED5 | c.1831C>A p.L611I | Missense Mutation (SNP) | VAF 25/232 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.039); called by muse, varscan2
- ZNF578 | c.1620A>T p.K540N | Missense Mutation (SNP) | VAF 28/269 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, varscan2
- ZNF578 | c.1744T>G p.S582A | Missense Mutation (SNP) | VAF 28/236 reads (12%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.006); called by muse, varscan2
- AGPS | c.709+42C>A | Intron (SNP) | VAF 16/148 reads (11%) | called by muse, varscan2
- BRWD1 | c.6572-43T>C | Intron (SNP) | VAF 32/239 reads (13%) | called by muse, varscan2
- BRWD1 | c.6572-44T>A | Intron (SNP) | VAF 32/234 reads (14%) | called by muse, varscan2
- BRWD1 | c.6572-45G>A | Intron (SNP) | VAF 32/232 reads (14%) | catalogued as rs1413401365; called by muse, varscan2
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 9/89 reads (10%) | called by muse, mutect2, varscan2
- CALCOCO2 | c.825+77T>A | Intron (SNP) | VAF 9/77 reads (12%) | called by mutect2, varscan2
- CBWD1 | c.708-93T>C | Intron (SNP) | VAF 6/56 reads (11%) | called by muse, varscan2
- COPS2 | c.715+50T>A | Intron (SNP) | VAF 9/43 reads (21%) | called by muse, varscan2
- COPZ1 | c.19-88G>A | Intron (SNP) | VAF 6/40 reads (15%) | called by muse, varscan2
- CRIPT | c.*53T>A | 3'UTR (SNP) | VAF 42/262 reads (16%) | called by muse, varscan2
- DROSHA | c.2367-73A>C | Intron (SNP) | VAF 28/143 reads (20%) | called by muse, mutect2
- EEF1AKMT2 | c.292-25A>T | Intron (SNP) | VAF 10/67 reads (15%) | called by muse, varscan2
- EIF3M | c.42+100C>A | Intron (SNP) | VAF 4/26 reads (15%) | called by mutect2, varscan2
- FCHO2 | c.1173+13A>G | Intron (SNP) | VAF 23/136 reads (17%) | called by muse, varscan2
- MSL3 | c.465+16T>A | Intron (SNP) | VAF 16/150 reads (11%) | called by muse, varscan2
- MSL3 | c.465+17G>A | Intron (SNP) | VAF 16/149 reads (11%) | catalogued as rs1375560978; called by muse, varscan2
- OR2AP1 | c.*96A>G | 3'UTR (SNP) | VAF 4/18 reads (22%) | catalogued as rs1012935800, COSV58726711; called by muse, mutect2
- PHTF2 | c.1119+65C>A | Intron (SNP) | VAF 7/44 reads (16%) | catalogued as rs1470892074; called by muse, varscan2
- SENP6 | c.2288+11A>T | Intron (SNP) | VAF 42/322 reads (13%) | called by muse, varscan2
- SPO11 | c.*15A>T | 3'UTR (SNP) | VAF 25/220 reads (11%) | called by muse, varscan2
- TACC1 | c.1917-92G>T | Intron (SNP) | VAF 4/80 reads (5%) | catalogued as rs1237407798; called by muse, mutect2
- TATDN1 | c.138+54T>A | Intron (SNP) | VAF 15/140 reads (11%) | called by muse, mutect2, varscan2
- TEX50 | c.-34T>A | 5'UTR (SNP) | VAF 9/106 reads (8%) | called by mutect2, varscan2
- USO1 | c.296-42A>T | Intron (SNP) | VAF 7/59 reads (12%) | called by muse, varscan2
- WASHC4 | c.2759-26T>A | Intron (SNP) | VAF 16/145 reads (11%) | called by muse, varscan2
